Surgical pathology report (de-identified scan), TCGA case TCGA-MT-A67F, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University of Minnesota, specimen TCGA-MT-A67F-01A (Primary Tumor).

[page 1 of 10]
ICDO-3
Carcinoma, squamous cell
keratinizing NOS 8071/3
Site: ^{path}mandibular gingiva, CO3.1
CCF Oral cavity CO6.9
JN 5/16/13

Tumor ID:

SPECIMEN(S):

A: Right maxillary alveolus

B: Level 1 A

C: Left lower canine

D: Midline floor of mouth margin

E: Posterior floor of mouth margin

F: RMT margin

G: Posterior buckle margin

H: Anterior buckle margin

I: Level 1 B

J: Level 2 A

K: Level 3

L: Level 4

M: Level 2 B

N: Excision of right maxillary alveolus

O: Right mandibular resection composite

FINAL DIAGNOSIS:

A. Oropharynx, right maxillary alveolus, biopsy (including AFS):

- Focal severe squamous dysplasia.
- No evidence of malignancy.

[page 2 of 10]
B. Lymph node, level 1A, lymph node dissection:

- No evidence of malignancy in three lymph nodes (0/3).

C. Tooth, left lower canine, excision:

- Tooth (gross only diagnosis).

D. Oropharynx, midline floor of mouth, margin biopsy (including DFS):

- Minor salivary gland with no evidence of carcinoma

E. Oropharynx, posterior floor of mouth, margin biopsy (including EFS):

- Squamous mucosa with chronic inflammation and fibrosis
- No evidence of carcinoma

F. Oropharynx, RMT, margin biopsy (including FFS):

- Squamous mucosa with no evidence of carcinoma

G. Oropharynx, posterior buckle, margin biopsy (including GFS):

- Squamous mucosa with dysplasia
- No evidence of carcinoma

H. Oropharynx, anterior buckle, margin biopsy (including HFS):

- Squamous mucosa with chronic no evidence of carcinoma

I. Lymph node, level 1B, lymph node dissection:

[page 3 of 10]
- No evidence of malignancy in five lymph nodes (0/4).
- Submandibular gland with no evidence of carcinoma

J. Lymph node, level 2A, lymph node dissection:

- No evidence of malignancy in nine lymph nodes (0/9).

K. Lymph node, level 3, lymph node dissection:

- No evidence of malignancy in twelve lymph nodes (0/12).

L. Lymph node, level 4, lymph node dissection:

- No evidence of malignancy in thirty lymph nodes (0/30).

M. Lymph node, level 2B, lymph node dissection:

- No evidence of malignancy in four lymph nodes (0/4).

N. Mucosa, right maxilla, wide local excision:

- Biopsy site with diathermy
- Squamous dysplasia

O. Bone and soft tissue, right mandible, composite resection:

- Squamous cell carcinoma, moderately differentiated keratinizing

type

- Invasive 1 cm
- 5.3 cm greatest dimension
- Invasive in to bone,

[page 4 of 10]
- Mandibular, soft tissue, and mucosal margins of resection free
of malignancy

- See Case summary

COMMENT:

CAP Case Summary

Specimen : Mandible

Tumor Focality: Single focus

Tumor Size

Greatest dimension: 5.3 cm, gross dimensions

Tumor Description: Gross subtypes polypoid, exophytic, ulcerated

Histologic Type: Squamous cell carcinoma, conventional type

Histologic Grade: G2: Moderately differentiated

Margins: Margins uninvolved by invasive carcinoma

**Distance from closest margin: 2 mm (lateral and medial soft tissue
margins)**

Lymph-Vascular Invasion: Not identified

Perineural Invasion: Present

Lymph Nodes, Extranodal Extension : Not identified

Pathologic Staging: pT4a pN0

Primary Tumor (pT): : Moderately advanced local disease.

Invasive, through cortical

[page 5 of 10]
Regional Lymph Nodes (pN): pN0:

Number of Lymph Nodes Examined: 64

Number of Lymph Nodes Involved: 0

Distant Metastasis (pM): Not Applicable

I have personally reviewed all specimens and or slides, including the listed special stains, and used them with my medical judgement to determine the final diagnosis.

CLINICAL HISTORY:

The patient is a -year-old female with oral cancer of mandible.

Operative procedure: Composite mandibular resection, lymph node dissection, and biopsies of alveolar ridge.

GROSS:

Received in multiple containers, each labeled with the patient's name, and medical record number.

Fifteen specimens are received, each labeled with the patient's name and hospital number.

A. The first container is received fresh for intraoperative consultation and labeled "A-right maxillary alveolus". The specimen consists of 0.5 x 0.4 x 0.2 cm pink-tan soft tissue, entirely submitted

[page 6 of 10]
for frozen section remnant in A1FS.

B. The next container is labeled "B-level 1A." The specimen consists of a 4.5 x 2.7 x 1.5 cm portion of yellow lobulated fibroadipose tissue. Sectioning reveals three lymph nodes measuring ranging from 0.6 to 1.0 cm in greatest dimension. All lymph nodes are entirely submitted in B1-B3, one lymph node in each.

C. The next container is labeled "C-left lower canine." The specimen consists of a 2.7 x 0.8 x 0.7 cm tan-white, firm and intact canine tooth. No soft tissue is attached. The specimen is for gross examination only.

D. The next container is received fresh for intraoperative consultation and the container is labeled "D-midline floor of mouth." The specimen consists of a 1.3 x 0.7 x 0.4 cm pink-red soft tissue. The specimen is entirely submitted for frozen section remnant in D1FS.

E. The next container is received fresh for intraoperative consultation and labeled "E - posterior floor of mouth margin." The specimen consists of a 2.5 x 0.4 x 0.3 cm strip of pink-tan soft tissue. The specimen is entirely submitted for frozen section remnant in E1FS.

F. The next container is received fresh for intraoperative

[page 7 of 10]
consultation and labeled "F-RMT margin." The specimen consists of 1.2 x 0.4 x 0.3 cm pink-tan soft tissue, entirely submitted for frozen section remnant in F1FS.

G. The next container is received fresh for intraoperative consultation and labeled "G-posterior buccal margin." The specimen consists of a 2.3 x 0.8 x 0.5 cm pink-tan soft tissue, entirely submitted for frozen section remnant in G1FS.

H. The next container is received fresh for intraoperative consultation and labeled "H-anterior buccal margin." The specimen consists of a 3.0 x 0.4 x 0.3 cm pink-tan soft tissue, entirely submitted for frozen section remnant in H1FS.

I. The next container is labeled "I-level 1B." The specimen consists of a 5.5 x 3.3 x 2.5 cm portion of tan-red fibroadipose tissue. Sectioning reveals a 3.5 x 2.0 x 1.3 cm and 5 gm yellow and lobulated salivary gland tissue. Sectioning reveals lobulated and unremarkable cut surface. Five lymph nodes ranging from 0.5 to 2.0 cm in greatest dimension are present within fibroadipose tissue. Representative sections:

J. The next container is labeled "J-level 2A." The specimen consists of a 4.8 x 4.0 x 2.5 cm portion of yellow lobulated fibroadipose tissue. Sectioning reveals nine lymph nodes ranging from 0.2 to 4.0 cm in greatest dimension. All lymph nodes are entirely

[page 8 of 10]
submitted.

Summary of Sections:

J1-J2 - one lymph node.

J3-J10 - one lymph node in each.

K. The next container is labeled "K-level 3." The specimen consists of a 5.5 x 2.3 x 2.0 cm portion of white-yellow fibroadipose tissue. Sectioning reveals 12 lymph nodes ranging from 0.2 to 1.5 cm in greatest dimension. All lymph nodes are entirely submitted.

Summary of Sections:

K1-K6 - one lymph node in each.

K7-K8 - three lymph nodes in each.

L. The next container is labeled "L-level 4." The specimen consists of two portions of yellow lobulated fibroadipose tissue measuring 5.5 x 2.7 x 2.0 cm in aggregate. Sectioning reveals 27 lymph nodes ranging from 0.1 to 1.0 cm in greatest dimension. All lymph nodes are entirely submitted.

Summary of Sections:

L1 - L5 - one lymph node in each.

L6-L9 - four lymph nodes in each.

L10 - three lymph nodes.

[page 9 of 10]
L11 - three lymph nodes, wrapped.

M. The next container is labeled "M-level 2B." The specimen consists of a 2.5 x 1.8 x 1.0 cm portion of yellow lobulated fibroadipose tissue. Sectioning reveals four lymph nodes ranging from 0.2 to 0.5 cm in greatest dimension. All lymph nodes are entirely submitted.

Summary of Sections:

M1-M2 - two lymph nodes in each.

N. The next container is labeled "N-excision of right maxillary alveolus." The specimen consists of a 1.3 x 0.3 x 0.2 cm white-red mucosal and submucosal soft tissue, entirely submitted in N1.

O. The next container is labeled "O-right mandibular resection composite." The specimen consists of right mandibular composite resection specimen measuring 7.8 cm from anterior to posterior, 4.7 cm from medial to lateral and 3.7 cm from superior to inferior. Eight teeth are present on the superior aspect. A 5.3 x 3.8 cm red papillary and ulcerated large mass is present on the gingival mucosa. A thin rim of tan-red mucosa is surrounding the mass. The specimen is inked as follows: Inferior = red, medial = green, lateral = yellow, anterior = orange, and posterior = black. On sectioning the mass invades up to 0.7 cm deep to the mucosal surface. The mass is 0.2 cm to lateral, 0.1 cm

[page 10 of 10]
to medial, 1.3 cm to anterior and 1.5 cm to posterior margin. Further sectioning reveals the mass invades mandibular bone tissue with 0.8 cm to the inferior mandibular bone margin. A 0.2 cm in diameter tan-white rubbery lymph node is present within submucosal soft tissue and close to the lateral margin. Representative sections:

Summary of Sections:

- O1 - lateral - anterior margin.
- O2 - lateral - posterior margin.
- O3 - medial - anterior margin.
- O4 - medial - posterior margin.
- O5 - mass with closest in medial margin.
- O6 - mass with a possible lymph node.
- O7 - mass with closest medial margin.
- O8 - mass.
- O9-O10 - mass with deep mandible.
- O11 - anterior mandibular margin, en face.
- O12 - posterior mandibular margin, en face (all bone sections are following fixation decalcification.)

Diagnostic Discrepancy		☒
(Dual/Synchronous Primary noted)		☒

Source: NCI Genomic Data Commons file a067e5ac-29c9-4889-a27f-6d2883f5f73b (TCGA-MT-A67F.38F89B3D-B228-4108-A454-FCA719E8DC6A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).